Gene-level copy-number profile of tumor specimen TCGA-XQ-A8TB-01A from TCGA case TCGA-XQ-A8TB, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 67.4 years (24,623 days).
Specimen TCGA-XQ-A8TB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.4eef35af-93f0-4ea9-b8c6-65b0445cd602.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XQ-A8TB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/30529183-d784-4b31-8cae-e6985654b52d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 6,220; copy number 2: 53,373; copy number 3: 181; copy number 4: 19; copy number 5: 3; copy number 6: 2; copy number 11: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XQ-A8TB-01A-11D-A363-01): tumor purity 0.99, ploidy 1.93, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:87,945,502–88,851,844, 16 genes (within-gene range 0–1): RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS, Y_RNA, LIPJ, RPL7P34, LIPF, NAPGP1, LIPK, KRT8P38, LIPN, RCBTB2P1, LIPM, ANKRD22.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:185,738,804–185,833,290, 1 gene, copy number 5 (within-gene range 2–5): FSIP2.
- chr5:155,491,336–155,493,598, 1 gene, copy number 5: AC008725.1.
- chr8:43,672,823–43,674,591, 2 genes, copy number 11: AC139365.2, AC139365.1.
- chr12:46,764,761–46,832,408, 1 gene, copy number 5 (within-gene range 2–5): SLC38A4.
- chr19:27,638,483–27,646,483, 2 genes, copy number 6: ERVK-28, AC112702.1.

Autosomal genes at a single copy (total copy number 1): 3,833. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
